Surgical pathology report (de-identified scan), TCGA case TCGA-BB-A6UO, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Johns Hopkins, specimen TCGA-BB-A6UO-01A (Primary Tumor).

[page 1 of 2]
- LAB RESULTS

SURG PATH REPORT
COLLECTION DATE/TIME:

PATH#: ~~_____~~

1st Specimen collected on
Accessioned on

FINAL DIAGNOSIS ----- Pathologist:

1) DEEP RIGHT TONGUE BASE (EXCISION): NEGATIVE FOR TUMOR.
2) LEFT HARD PALATE (EXCISION): NEGATIVE FOR TUMOR.
3) DEEP SKULL BASE (EXCISION): NEGATIVE FOR TUMOR.
4) LEFT NASOPHARYNX (EXCISION): NEGATIVE FOR TUMOR.
5) DEEP MIDLINE HARD PALATE (EXCISION): NEGATIVE FOR TUMOR.
6) RIGHT SOFT PALATE (EXCISION): NEGATIVE FOR TUMOR.
7) LEFT VALLECULA (EXCISION): NEGATIVE FOR TUMOR.
8) PARAPHARYNGEAL SPACE FAT (EXCISION): NEGATIVE FOR TUMOR.
9) LEFT PHARYNX (EXCISION): NEGATIVE FOR TUMOR.
10) MIDLINE HARD PALATE (EXCISION): NEGATIVE FOR TUMOR.
11) TONGUE, LEFT MANDIBLE AND POSTERIOR PHARYNGEAL WALL (COMPLETE
SUBTOTAL GLOSSECTOMY):
SPECIMEN TYPE:
COMPOSITE SUBTOTAL GLOSSECTOMY AND HEMIMANDIBULECTOMY

TUMOR SITE:
ORAL CAVITY (TONGUE)

TUMOR SIZE:
GREATEST DIMENSION: 7.0 CM

HISTOLOGIC TYPE:
CARCINOMAS OF UPPER AERODIGESTIVE TRACT: SQUAMOUS CELL
CARCINOMA, CONVENTIONAL

HISTOLOGIC GRADE:
G2: MODERATELY DIFFERENTIATED

EXTENT OF INVASION (7th Edition AJCC):
PRIMARY TUMOR (pT):
pT4a: ORAL CAVITY: TUMOR INVADES ADJACENT STRUCTURES (THROUGH
MANDIBULAR BONE AND INTO SOFT TISSUES OF THE FLOOR OF THE MOUTH)

SPECIFY: NUMBER EXAMINED: 30
NUMBER INVOLVED: 3

REGIONAL LYMPH NODES (pN):
pN2b: METASTASIS IN MULTIPLE IPSILATERAL LYMPH NODES,
NOT MORE THAN 6 CM IN GREATEST DIMENSION

EXTRACAPSULAR EXTENSION OF NODAL TUMOR: PRESENT

DISTANT METASTASIS (pM):
pMX: CANNOT BE ASSESSED

MARGINS:
MARGINS UNINVOLVED BY TUMOR (SEE ALSO PARTS 1-10).
TUMOR APPROACHES WITHIN 1 MM OF THE POSTERIOR PHARYNGEAL SOFT TISSUE
SPECIMEN EDGE (PART 11)

*** Unofficial lab results - do not file in patient chart. ***
*** Contact medical records for official chart copy. ***
UNLESS OTHERWISE NOTED ON THE DETAIL PAGE, ALL LAB RESULTS PERFORMED AT:

ICD-O-3

Carcinoma, squamous
cell NOS 8070/3

Site: Tongue NOS C02.9
JW 7/24/13

[page 2 of 2]
- LAB RESULTS

VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION:
INDETERMINATE

NEURAL INVASION:
PERINEURAL AND INTRANEURAL INVASION ARE PRESENT

12) LYMPH NODE, LEFT AXILLA (EXCISION): ONE (1) LYMPH NODE AND
ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

13) LYMPH NODES, LEFT NECK LEVEL 2B (EXCISION): SIX (6) LYMPH NODES
AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

14) LYMPH NODES, RIGHT NECK LEVEL 1B (EXCISION): TWO (2) LYMPH NODES
AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

15) DEEP SKULL BASE (EXCISION): BENIGN SKELETAL MUSCLE, BONE AND
FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR. CELLULAR TRILINEAGE MARROW
WITH FULL MATURATION.

16) PARAPHARYNGEAL SPACE (EXCISION): BENIGN SKELETAL MUSCLE AND
FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

17) LYMPH NODES, LEFT NECK LEVELS 1-3 (EXCISION):

LEVEL 1: BENIGN FIBROADIPOSE TISSUE.

LEVEL 2: METASTATIC SQUAMOUS CELL CARCINOMA INVOLVING ONE (1) OF
TWO (2) LYMPH NODES (1.5 CM), WITH EXTRANODAL EXTENSION.

LEVEL 3: METASTATIC SQUAMOUS CELL CARCINOMA INVOLVING TWO (2) OF
SEVENTEEN (17) LYMPH NODES (0.6 AND 0.3 CM); EXTRACAPSULAR EXTENSION
IS NOT IDENTIFIED.

See for official report.

Reported by:

Final Report Signed on

*** Unofficial lab results - do not file in patient chart. ***

*** Contact medical records for official chart copy. ***

UNLESS OTHERWISE NOTED ON THE DETAIL PAGE. ALL LAB RESULTS PERFORMED AT:

Source: NCI Genomic Data Commons file 6b0dd320-df68-465b-b0d6-18461a85c539 (TCGA-BB-A6UO.FB282F08-6047-4844-90A4-AA4B04911ED6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).